CCDI case PBCEPC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/486a73d7-ff42-4bcb-b436-48ce12e45542

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Vital status: Dead.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 5.9 years (2,173 days).

Biospecimens (3 samples)
- Sample 0DQHAC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQHB4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQHBM: Tissue type: Tumor; Specimen type: Solid Tissue.
